CCDI case PBCBCB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fc791c42-45fd-4453-825e-f03fa20f2d73

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,768 days).

Biospecimens (3 samples)
- Sample 0DSW97: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSW9F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSW9W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
